Somatic mutation profile of tumor specimen MP2PRT-PAUDWB-TMP1-B (aliquot MP2PRT-PAUDWB-TMP1-B-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUDWB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.7 years (2,084 days).
Specimen MP2PRT-PAUDWB-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59d8527e-1670-4dcb-8748-2c50b87bfdef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUDWB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUDWB-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6b137f8-244e-410f-aa89-5917da96f54c

The open-access MAF lists 57 somatic variants for this specimen: 43 protein-altering or splice-affecting, 11 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 11, Nonsense Mutation 5, In Frame Ins 3, Intron 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.2317C>T p.Q773* | Nonsense Mutation (SNP) | VAF 70/667 reads (10%) | catalogued as rs758555274, COSV56443963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 24/91 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- ADAMTS16 | c.3263G>A p.R1088Q | Missense Mutation (SNP) | VAF 164/396 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.117); catalogued as rs374351561; called by muse, mutect2, varscan2
- C15orf39 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 42/510 reads (8%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.852); catalogued as rs778936459; called by muse, mutect2
- CAND1 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV73338629, COSV73338658; called by muse, mutect2
- CREBBP | c.4448T>C p.I1483T | Missense Mutation (SNP) | VAF 161/410 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201719835, COSV52113979, COSV52115041, COSV52119010; called by muse, mutect2, varscan2
- EVC2 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 160/619 reads (26%) | catalogued as COSV60395332; called by muse, mutect2, varscan2
- FGFR2 | c.205G>A p.V69M | Missense Mutation (SNP) | VAF 38/497 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs371714070; called by muse, mutect2
- HLA-DQA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 135/639 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144060347; called by muse, varscan2
- IRX6 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 107/380 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as rs762498626, COSV51862051; called by muse, mutect2, varscan2
- MEGF8 | c.7831C>T p.R2611C (on ENST00000251268 / NM_001271938.2; = p.R2544C on NM_001410.3) | Missense Mutation (SNP) | VAF 62/649 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs773724721; called by muse, mutect2
- MGLL | c.719G>A p.R240H (on ENST00000398104 / NM_001003794.2; = p.R250H on NM_007283.6) | Missense Mutation (SNP) | VAF 96/334 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs372843202; called by muse, varscan2
- MUC16 | c.18607G>A p.D6203N | Missense Mutation (SNP) | VAF 104/303 reads (34%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.065); catalogued as COSV101198459; called by muse, mutect2, varscan2
- PEX5 | c.1636C>T p.R546C (on ENST00000420616; = p.R538C on NM_000319.5) | Missense Mutation (SNP) | VAF 122/410 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.208); catalogued as rs759334733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBMXL3 | c.608C>G p.P203R | Missense Mutation (SNP) | VAF 33/610 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.198); catalogued as rs933077165; called by muse, mutect2
- ROBO1 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 88/207 reads (43%) | SIFT tolerated (0.88); PolyPhen benign (0.348); catalogued as rs968398388; called by muse, mutect2, varscan2
- SCN1A | c.1765G>A p.D589N | Missense Mutation (SNP) | VAF 133/394 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.108); catalogued as rs781481818, COSV100321134; called by muse, mutect2, varscan2
- SERPINC1 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 137/427 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as rs374205395, CD961789; called by muse, mutect2, varscan2
- SLC38A10 | c.2798G>A p.R933Q | Missense Mutation (SNP) | VAF 149/647 reads (23%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs1288801757; called by muse, mutect2, varscan2
- TDRD6 | c.6225G>A p.W2075* | Nonsense Mutation (SNP) | VAF 25/378 reads (7%) | catalogued as rs1182826209, COSV60179028; called by muse, mutect2
- TNFRSF19 | c.466G>A p.V156M | Missense Mutation (SNP) | VAF 97/293 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs116629724; called by muse, mutect2, varscan2
- TTN | c.94504C>G p.Q31502E (on ENST00000591111; = p.Q24078E on NM_003319.4) | Missense Mutation (SNP) | VAF 94/362 reads (26%) | PolyPhen probably damaging (0.948); catalogued as rs1380008073; called by muse, mutect2, varscan2
- ZBTB25 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 23/490 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1407762870; called by muse, mutect2
- ATG16L2 | c.933_935dup p.R312dup | In Frame Ins (INS) | VAF 89/283 reads (31%) | called by mutect2, pindel, varscan2
- CCDC65 | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 71/248 reads (29%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CER1 | c.695T>A p.V232E | Missense Mutation (SNP) | VAF 87/323 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CPS1 | c.4055C>T p.S1352F | Missense Mutation (SNP) | VAF 120/306 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- DEFB110 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSIP2 | c.10405A>T p.K3469* | Nonsense Mutation (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- GTF3C1 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 39/513 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); called by muse, mutect2
- HLA-C | c.180_181insCTC p.F60_D61insL | In Frame Ins (INS) | VAF 120/542 reads (22%) | called by mutect2, pindel
- IGKV1OR2-108 | c.353delinsCCCC | In Frame Ins (INS) | VAF 44/135 reads (33%) | called by mutect2*, pindel, varscan2*
- KANK2 | c.111dup p.Y38Lfs*15 | Frame Shift Ins (INS) | VAF 174/510 reads (34%) | called by mutect2, pindel, varscan2
- KDM5D | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 161/475 reads (34%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- KLHL34 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 227/485 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MRPL15 | c.197G>A p.G66D | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NACC1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 45/513 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR2A7 | c.138dup p.L47Afs*74 | Frame Shift Ins (INS) | VAF 81/536 reads (15%) | called by mutect2, pindel, varscan2
- PPM1E | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 53/290 reads (18%) | called by muse, mutect2, varscan2
- SIN3A | c.503T>G p.V168G | Missense Mutation (SNP) | VAF 74/277 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TOM1L1 | c.293A>C p.K98T | Missense Mutation (SNP) | VAF 57/212 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- USP15 | c.2878G>A p.E960K (on ENST00000280377 / NM_001351159.2; = p.E931K on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/218 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ZFPM2 | c.1282C>A p.Q428K | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.51); PolyPhen benign (0.01); called by muse, mutect2
- CDK20 | c.972C>T p.H324= (on ENST00000325303 / NM_001039803.3; = p.H303= on NM_012119.4) | Silent (SNP) | VAF 166/418 reads (40%) | catalogued as rs780624824; ClinVar: likely benign; called by muse, mutect2, varscan2
- DACH1 | c.1263G>A p.Q421= | Silent (SNP) | VAF 32/339 reads (9%) | called by muse, mutect2
- FSHR | c.1683C>T p.I561= | Silent (SNP) | VAF 46/500 reads (9%) | catalogued as rs757713421, COSV58623930; called by muse, mutect2
- LRRC8D | c.561C>A p.P187= | Silent (SNP) | VAF 54/201 reads (27%) | called by muse, mutect2, varscan2
- MUC16 | c.15621A>G p.T5207= | Silent (SNP) | VAF 12/440 reads (3%) | catalogued as COSV67453275; called by muse, mutect2
- PAPPA2 | c.19C>T p.L7= | Silent (SNP) | VAF 109/285 reads (38%) | catalogued as COSV62780013; called by muse, mutect2, varscan2
- RGP1 | c.552G>A p.E184= | Silent (SNP) | VAF 35/444 reads (8%) | catalogued as rs750260687; called by muse, mutect2
- STX8 | c.165C>T p.I55= | Silent (SNP) | VAF 66/292 reads (23%) | catalogued as rs749527313, COSV60489686; called by muse, mutect2, varscan2
- TNXB | c.4599C>T p.G1533= (on ENST00000647633; = p.G1286= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/718 reads (5%) | called by muse, mutect2
- TONSL | c.810G>A p.R270= | Silent (SNP) | VAF 112/364 reads (31%) | called by muse, mutect2, varscan2
- ZSWIM9 | c.1575G>A p.G525= | Silent (SNP) | VAF 54/562 reads (10%) | catalogued as rs1219439826; called by muse, mutect2, varscan2
- ASIC2 | c.556-179869G>A | Intron (SNP) | VAF 36/533 reads (7%) | called by muse, mutect2
- KCNQ1 | c.1394-7728C>T | Intron (SNP) | VAF 46/527 reads (9%) | called by muse, mutect2
- LRGUK | c.1843+7571C>G | Intron (SNP) | VAF 140/409 reads (34%) | called by muse, mutect2, varscan2
